Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3SO, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3SO-01A (Primary Tumor).

[page 1 of 4]
Case#:

Sample

Gender: Male

DOB:

Race:

Report Date:

TIPAA Discrepancy		X

Pathology Report:

ICD-O-3

carcinoma, urothelial, NOS
8120/3

Surgical Pathology Report

site:

bladder, wall, lateral

C67.2

4-9-12 RD

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph node; dissection:

- Six lymph nodes, no tumor (0/6).

B. Left pelvic lymph node; dissection:

- One lymph node, positive for metastatic urothelial carcinoma (1/1).
- Lymph nodal tumor focus measures 1.8 cm in greatest dimension.
- Extranodal tumor extension present.

C. Left pelvic lymph node, dissection:

- Nine lymph nodes, no tumor (0/9).

D. Urinary bladder, prostate, seminal vesicles and vas deferens; cystoprostatectomy:

- Invasive urothelial carcinoma of the bladder, see pathologic parameters.
- Prostate with high grade prostatic intraepithelial neoplasia.
- One perivesical lymph node, no tumor (0/1).

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue.
4. Tumor distribution: Solitary, left lateral bladder wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Positive for tumor (1/17).
9. pTNM: pT3a,N1,MX.

Effective

this Checklist utilizes the edition TNM staging

[page 2 of 4]
system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

[] MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MB, PhD

Electronically Signed Out by [] MD

Clinical History:

The patient is a -year-old male with invasive urothelial carcinoma, high grade undergoing cystoprostatectomy.

Specimens Received:

A: Right pelvic lymph node

B: Left pelvic lymph node

C: Left pelvic lymph node

D: Bladder, prostate, seminal vesicle, vas deferens

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin is a 5.5 x 5.5 x 1.5 cm aggregate of yellow-tan lobulated adipose tissue. The specimen is dissected for lymph nodes and 7 are found measuring 0.3-4.5 cm in greatest dimension and are submitted as follows:

A1: 3 lymph node candidates

A2-A4: 1 bisected lymph node in each cassette

A5-A6: 1 lymph node, sectioned

B. The second container is additionally identified as, "left pelvic lymph node". Received fresh for intraoperative consult is a 3.5 x 2.4 x 1.6 cm yellow-tan tissue fragment which is bisected to reveal a 2.2 cm white-tan lymph node candidate. A representative section is frozen and called "metastatic carcinoma" by Dr. [] The frozen remnant is submitted as B1 FS and the remaining lymph node candidate is submitted as B2-B4.

C. The third container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin is a 10.5 x 5.5 x 1.5 cm aggregate of

[page 3 of 4]
yellow-tan lobulated adipose tissue. The specimen is dissected for lymph node candidates. Sections are submitted as follows:

C1: 5 lymph node candidates

C2: 2 lymph node candidates

C3: 1 lymph node candidate, bisected

C4: 1 lymph node candidate

C5: 1 lymph node candidate

C6-7: 1 lymph node, sectioned

D. The fourth container is additionally identified as, "bladder, prostate, seminal vesicles and vas deferens".

Received fresh and placed in formalin is a 393.7 g, 16.5 x 15.5 x 4.5 cm cystoprostatectomy specimen consisting of a 7 x 6 x 3.5 cm bladder with attached mesenteric fat and a 4.3 x 4 x 3 cm prostate. The right seminal vesicles measure 4.2 x 1.7 x 0.9 cm and right vas deferens measures 9.5 cm in length by 0.2-0.5 cm in diameter. The left seminal vesicles measures 4.5 x 1.6 x 0.8 cm and left vas deferens measures 10.5 cm in length by 0.2-0.5 cm in diameter. The right ureteral stump measures 1.6 cm in length by 0.6 cm in diameter, the left measures 2 cm in length and 0.6 cm in diameter, and both demonstrate intact, patent lumens to the trigone.

The right half of the prostate is inked blue and the left half is inked black.

The soft tissue surrounding the bladder is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations. Approximately 50% of the gland is submitted.

The opened bladder reveals a 2.8 x 2.7 cm indurated, tan-yellow shaggy ulcerated mass with a hyperemic rim in the left lateral wall which partially extends to the anterior, posterior, and trigone and involving the left ureter orifice. The ulceration is 5 cm from the distal urethral margin and 0.7 cm from the prostate base. On cut section, the mass extends to the serosa, possibly the peri-vesicular adipose tissue to a depth of 1.1 cm and is 0.2 cm from the deep margin. The surrounding bladder mucosa is tan-pink to red and edematous with a uniform 0.9 cm wall thickness.

Gross photographs are taken.

Representative sections are submitted as follows:

D1: Left ureter margin

D2: Right ureter margin

D3: Distal urethral margin

D4: Prostatic apical margin

D5-D8: Representative right prostate

D9-D12 Representative left prostate

[page 4 of 4]
D13: Right seminal vesicles

D14: Left seminal vesicles

D15: Bladder mass and proximal prostate

D16-D17: Bladder mass, deepest section, and closest approach to soft tissue resection margin

D18-D21: Bladder mass and surrounding grossly uninvolved mucosa

D22: Uninvolved posterior to right-lateral bladder wall

D23: Uninvolved bladder dome

D24: Uninvolved anterior bladder wall with possible lymph node

D25-D26: Distal ureter margin

xx

[], M.D.

Intraoperative Consult Diagnosis:

B1 FS: Metastatic carcinoma per Dr.[]

Source: NCI Genomic Data Commons file f072b279-5cd2-4b63-8bfa-98433677985d (TCGA-FD-A3SO.9F88F244-C30A-409F-BA44-94BEA0177116.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).